Somatic mutation profile of tumor specimen TCGA-K4-A4AC-01A (aliquot TCGA-K4-A4AC-01A-21D-A26M-08) from TCGA case TCGA-K4-A4AC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 83.9 years (30,655 days).
Specimen TCGA-K4-A4AC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1deff211-f17b-4e7f-b3f7-c20ce20a5b93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A4AC-10A (Blood Derived Normal), aliquot TCGA-K4-A4AC-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e6f129f-d78d-428c-978b-c2e790341bce

The open-access MAF lists 164 somatic variants for this specimen: 120 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 41, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, 3'UTR 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ2 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473371, CM053934, COSV54659990; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV59382346; called by muse, mutect2, varscan2
- ABCA2 | c.4430G>A p.R1477H (on ENST00000614293; = p.R1447H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201657940, COSV55796799; called by muse, mutect2, varscan2
- AKAP6 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55203320; called by muse, mutect2, varscan2
- ALDH4A1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV51889807; called by muse, mutect2, varscan2
- ALG10B | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV58142103; called by muse, mutect2, varscan2
- APOA1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52635185; called by muse, mutect2, varscan2
- ARHGEF25 | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV54084073; called by muse, mutect2, varscan2
- ARID2 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100537374, COSV57594596; called by muse, mutect2, varscan2
- ASGR2 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV54689161, COSV54691237; called by muse, mutect2, varscan2
- ATF4 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs1167819293, COSV57477496; called by muse, mutect2, varscan2
- ATRNL1 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.272); catalogued as COSV61796091; called by muse, mutect2, varscan2
- ATXN10 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99426179; called by muse, mutect2, varscan2
- BMP8A | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as COSV100090089; called by mutect2, varscan2
- BRINP1 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 17/175 reads (10%) | catalogued as rs764781191, COSV99774976; called by muse, mutect2, varscan2
- BTNL8 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754512426, COSV51456653; called by muse, mutect2, varscan2
- C8orf33 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58895254; called by muse, mutect2, varscan2
- CACNG5 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV50054663; called by muse, mutect2, varscan2
- CATSPER1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV56408732; called by muse, mutect2, varscan2
- CATSPER4 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV58792104; called by muse, mutect2, varscan2
- CD163L1 | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as rs147256239; called by muse, mutect2, varscan2
- CDC25C | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60398079; called by muse, mutect2, varscan2
- CDK12 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as COSV70999047; called by muse, mutect2, varscan2
- CDS1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV55686384; called by muse, mutect2, varscan2
- CES4A | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100110029, COSV58654078; called by muse, mutect2, varscan2
- CHD3 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV57872122; called by muse, mutect2, varscan2
- CHKB | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56414831, COSV56417487; called by muse, mutect2, varscan2
- CLPTM1 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV61610861; called by muse, mutect2, varscan2
- CLSTN1 | c.2041G>C p.E681Q (on ENST00000377298 / NM_001009566.3; = p.E671Q on NM_014944.4) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV63646271; called by muse, mutect2, varscan2
- COPS5 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99138243; called by muse, mutect2
- CUBN | c.3108A>C p.L1036F | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV64706856; called by muse, mutect2, varscan2
- DYRK1B | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59912769; called by muse, mutect2, varscan2
- EIF4H | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV56081388, COSV56081769; called by muse, mutect2, varscan2
- ELANE | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV55047344; called by muse, mutect2, varscan2
- ERCC4 | c.2242A>G p.M748V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61310512; called by muse, mutect2, varscan2
- FAS | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV58238085; called by muse, mutect2, varscan2
- FKBP4 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772045995, COSV50008789; called by muse, mutect2, varscan2
- FLT4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs747487993, COSV56097066; called by muse, mutect2, varscan2
- FNDC11 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100918778; called by muse, mutect2
- GASK1B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV56704003; called by muse, mutect2, varscan2
- GIMAP8 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV56229517; called by muse, mutect2
- GLIPR1L2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as COSV100248513, COSV100248642; called by muse, mutect2
- GORASP1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV56529757; called by muse, mutect2, varscan2
- GPAM | c.1667T>C p.F556S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV62080117; called by muse, mutect2
- GPR158 | c.3470C>G p.S1157* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100893130; called by muse, mutect2, varscan2
- GPR61 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs571875540, COSV68177288; called by muse, mutect2, varscan2
- HOXC9 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777643587, COSV57716328; called by muse, mutect2, varscan2
- IKZF2 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59575992; called by muse, mutect2
- IL1RAP | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99299349; called by muse, mutect2, varscan2
- IPO7 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV101121806, COSV65684755; called by muse, mutect2
- IPO7 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65684053; called by muse, mutect2, varscan2
- IPO9 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761738400, COSV64232687; called by muse, mutect2, varscan2
- ITGAL | c.446-1G>A p.X149_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63319875; called by muse, mutect2, varscan2
- KCTD3 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52063870; called by muse, mutect2, varscan2
- KIAA1109 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV52669165, COSV99151183; called by muse, mutect2
- KMT2A | c.7596G>T p.E2532D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.373); catalogued as COSV63281238; called by muse, mutect2, varscan2
- LILRA1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV52177456; called by muse, mutect2, varscan2
- LRRTM1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs777356920, COSV54437772; called by muse, mutect2, varscan2
- MAB21L4 | c.518C>T p.S173L (on ENST00000388934 / NM_001085437.3; = p.S5L on NM_024861.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs775942728, COSV56742690; called by muse, mutect2, varscan2
- MBP | c.871-1G>T p.X291_splice (on ENST00000355994 / NM_001025101.2; = p.X173_splice on NM_002385.3) | Splice Site (SNP) | VAF 13/93 reads (14%) | catalogued as COSV62828370; called by muse, mutect2, varscan2
- MBTPS2 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV63410575; called by muse, varscan2
- MIOS | c.1299G>C p.M433I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100402653; called by muse, mutect2
- MPI | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100086258, COSV60397772; called by muse, mutect2, varscan2
- MTFR1L | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.378); catalogued as COSV62523841; called by muse, mutect2, varscan2
- MUC16 | c.16754C>A p.S5585* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV101199218; called by muse, mutect2, varscan2
- MYO9B | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68276659; called by muse, mutect2, varscan2
- NLGN2 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV56657814; called by muse, mutect2, varscan2
- NUB1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100879259; called by muse, mutect2
- OR10K1 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as rs777382123, COSV56870310; called by muse, mutect2, varscan2
- OR14K1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771821916, COSV51720124, COSV99315318; called by muse, mutect2, varscan2
- OR2A2 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs978122275, COSV68870937; called by muse, mutect2
- OR2C1 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as COSV59239476; called by muse, mutect2
- OR5AP2 | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.244); catalogued as COSV57256804; called by muse, mutect2
- PDE6C | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101008640; called by muse, mutect2
- PEG3 | c.3763C>T p.Q1255* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99688196; called by muse, mutect2, varscan2
- RBM26 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.505); catalogued as COSV57390789; called by muse, mutect2, varscan2
- RECQL5 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs921759641, COSV58636851; called by muse, mutect2, varscan2
- RHBDL3 | c.919C>G p.R307G | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52184289, COSV52184329; called by muse, mutect2
- RHOB | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- ROR2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.202); catalogued as rs761854477, COSV65218280; called by muse, mutect2
- RPS6KA4 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99589891; called by muse, mutect2
- RUFY2 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.554); catalogued as COSV101175805; called by muse, mutect2
- SEMA6D | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100316725; called by muse, mutect2
- SERPINB13 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54029208, COSV99500959; called by muse, mutect2
- SH2B1 | c.988C>G p.R330G | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59460233; called by muse, mutect2, varscan2
- SLC1A6 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs751345541, COSV55667505, COSV55667644; called by muse, mutect2, varscan2
- SLC30A3 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51983761; called by muse, mutect2, varscan2
- SLC5A9 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs1232655073, COSV52581751; called by muse, mutect2, varscan2
- SLC7A4 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60382228; called by muse, mutect2, varscan2
- SOX2 | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051647, COSV57620835; called by mutect2, varscan2
- SRCAP | c.9122G>T p.R3041L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV52666852; called by muse, mutect2, varscan2
- STK39 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1483235189, COSV63599959; called by muse, mutect2
- TET1 | c.1941G>C p.Q647H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65381617; called by muse, mutect2, varscan2
- THSD7B | c.4199A>T p.Q1400L (on ENST00000272643; = p.Q1398L on NM_001316349.2) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55649371; called by muse, mutect2, varscan2
- TMED1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.312); catalogued as rs762064138, COSV53033058; called by muse, mutect2, varscan2
- TMEM59 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52368884; called by muse, mutect2, varscan2
- TPO | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs150812908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAM1L1 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100162408, COSV60291092; called by muse, mutect2, varscan2
- TRMT11 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as COSV57671806; called by muse, mutect2, varscan2
- TTN | c.40982T>A p.L13661H (on ENST00000591111; = p.L6237H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV59864000, COSV59991128; called by muse, mutect2, varscan2
- TUBGCP4 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as COSV99538948; called by muse, mutect2
- UHRF1BP1L | c.3082C>G p.Q1028E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.035); catalogued as COSV54434030; called by muse, mutect2, varscan2
- VARS1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV63304151; called by muse, mutect2, varscan2
- VPS13B | c.3728G>A p.R1243K | Missense Mutation (SNP) | VAF 252/335 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62131743; called by muse, mutect2, varscan2
- ZC3H7B | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV60960244; called by muse, mutect2, varscan2
- ZC3H7B | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV60960257; called by muse, mutect2, varscan2
- ZMYND8 | c.559G>T p.E187* (on ENST00000311275 / NM_001363741.2; = p.E207* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53695047; called by muse, mutect2, varscan2
- ZNF334 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV61617896; called by muse, mutect2, varscan2
- ZNF560 | c.1737A>T p.K579N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56865044; called by muse, mutect2, varscan2
- ZNF567 | c.707A>G p.N236S (on ENST00000536254 / NM_001322913.1; = p.N205S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100658731; called by muse, mutect2
- ZNF600 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV57741188; called by muse, mutect2, varscan2
- ZNHIT2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.833); catalogued as COSV54204280, COSV54205392, COSV54205400; called by muse, mutect2
- CNP | c.1047dup p.E350Rfs*60 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel
- DSC3 | c.790del p.V264Wfs*17 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- GRIN2C | c.218dup p.N73Kfs*24 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- MBTPS2 | c.276dup p.L93Sfs*16 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by pindel, varscan2
- MYOM3 | c.596_597del p.F199Sfs*19 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- POLQ | c.515_521del p.M172Tfs*24 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PRPF38B | c.792_794del p.R265del | In Frame Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- AHNAK | c.4212G>C p.V1404= | Silent (SNP) | VAF 53/243 reads (22%) | catalogued as COSV57202354; called by muse, mutect2, varscan2
- ARHGEF10 | c.2862A>G p.E954= (on ENST00000398564; = p.E929= on NM_014629.4) | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV50642244; called by muse, mutect2, varscan2
- ASRGL1 | c.861C>T p.A287= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs766697902, COSV57123232; called by muse, mutect2, varscan2
- ATP13A5 | c.165C>T p.P55= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as COSV60865067; called by muse, mutect2, varscan2
- ATP1A3 | c.3012C>T p.Y1004= (on ENST00000545399 / NM_001256214.2; = p.Y991= on NM_152296.5) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs372919447; called by muse, mutect2, varscan2
- ATXN10 | c.714G>A p.L238= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99426181; called by muse, mutect2
- CAPN5 | c.549C>G p.V183= (on ENST00000456580; = p.V143= on NM_004055.5) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53685268; called by muse, mutect2, varscan2
- CFAP70 | c.3198T>C p.N1066= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV60280646; called by muse, mutect2, varscan2
- COPS4 | c.466C>T p.L156= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs762663194, COSV52313517; called by muse, mutect2, varscan2
- CTSZ | c.234C>T p.S78= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99413494; called by muse, mutect2
- CYP4A22 | c.180C>T p.F60= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs754219380, COSV53737819; called by muse, mutect2, varscan2
- DCTN6 | c.33T>A p.I11= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV55316940; called by muse, mutect2, varscan2
- DSCAM | c.1764C>T p.S588= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs1207742295, COSV68019990; called by muse, mutect2
- EXOSC10 | c.1974C>T p.I658= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58663340; called by muse, varscan2
- EXOSC10 | c.1818C>T p.L606= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV58663350; called by mutect2, varscan2
- FAM117B | c.1761T>C p.A587= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV57416100, COSV57416745; called by muse, mutect2, varscan2
- GGPS1 | c.840G>T p.G280= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1274734705, COSV51396840, COSV51396963; called by muse, mutect2, varscan2
- GHITM | c.648C>A p.I216= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV64538170; called by muse, mutect2, varscan2
- INHBB | c.456C>T p.L152= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs145813735; called by muse, mutect2, varscan2
- ITPR3 | c.3330C>T p.I1110= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV65405136; called by muse, mutect2, varscan2
- KALRN | c.4179C>T p.F1393= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53751628; called by muse, mutect2, varscan2
- LCMT2 | c.1068G>A p.K356= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1434216611, COSV99979998, COSV99980282; called by muse, mutect2, varscan2
- MTOR | c.2865G>C p.L955= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV63867970; called by muse, mutect2, varscan2
- MYH4 | c.1965C>T p.F655= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55111331; called by muse, mutect2, varscan2
- PARP14 | c.1308A>T p.A436= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV71734054; called by muse, mutect2, varscan2
- PCDHA3 | c.1284G>A p.R428= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as rs782571599, COSV63538565; called by muse, mutect2, varscan2
- PDIA3 | c.9C>T p.L3= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100294991; called by muse, mutect2
- PIGO | c.1884G>A p.L628= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs746618634, COSV53052287; called by muse, mutect2, varscan2
- PPP4R3B | c.1440C>G p.T480= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55401225; called by muse, mutect2, varscan2
- RNF39 | c.21G>C p.T7= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV54992403, COSV99748382; called by muse, mutect2, varscan2
- RP1L1 | c.276C>T p.A92= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs372461532, COSV61443627; called by muse, mutect2, varscan2
- SH2D7 | c.669C>T p.L223= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV51947381; called by muse, mutect2, varscan2
- SLC7A4 | c.1059C>T p.F353= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV60382232; called by muse, mutect2, varscan2
- SLCO1C1 | c.660T>C p.N220= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56867753; called by muse, mutect2, varscan2
- ST8SIA1 | c.766C>T p.L256= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53949922; called by muse, mutect2, varscan2
- STK11IP | c.2187G>C p.R729= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55245313; called by muse, mutect2, varscan2
- SYNPO | c.1101C>T p.L367= (on ENST00000394243 / NM_001166208.2; = p.L123= on NM_007286.6) | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs1347885028, COSV56937900; called by muse, mutect2, varscan2
- TBX5 | c.723C>T p.D241= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs368563052; called by muse, mutect2, varscan2
- TPCN2 | c.825C>T p.P275= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs754612840, COSV53726720, COSV99593468; called by muse, mutect2, varscan2
- ZNF235 | c.1764C>T p.A588= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV52154990; called by muse, mutect2
- ZNF276 | c.264G>A p.S88= (on ENST00000443381 / NM_001113525.2; = p.S13= on NM_152287.4) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs762800359, COSV57065426; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498985 G>A | 5'Flank (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- MRTFB | c.1079+151A>T | Intron (SNP) | VAF 10/50 reads (20%) | catalogued as COSV57955840; called by muse, mutect2, varscan2
- TMEM132A | c.*1C>G | 3'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99134583; called by muse, mutect2
